Somatic mutation profile of tumor specimen TCGA-AO-A03T-01A (aliquot TCGA-AO-A03T-01A-21W-A050-09) from TCGA case TCGA-AO-A03T, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 42.5 years (15,540 days).
Specimen TCGA-AO-A03T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b36a8121-bc02-4a2b-9372-1ca6682c2be3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A03T-10A (Blood Derived Normal), aliquot TCGA-AO-A03T-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c5d4a8-7574-4738-a30f-28e2a0488fda

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Frame Shift Del 8, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, Intron 2, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.696T>A p.S232R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV52223062; called by muse, mutect2, varscan2
- ARHGAP32 | c.2382T>G p.D794E (on ENST00000310343 / NM_001378025.1; = p.D445E on NM_014715.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100086965; called by muse, mutect2
- ATP5PB | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV63854047; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2663T>C p.V888A | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV63245264; called by muse, mutect2, varscan2
- BRWD1 | c.1003+2T>C p.X335_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100312866; called by muse, mutect2
- C7 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376674018; called by muse, mutect2, varscan2
- CASQ2 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54770893; called by muse, mutect2, varscan2
- CEP120 | c.2865G>C p.L955F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100070838; called by muse, mutect2
- CFAP61 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55631423; called by muse, mutect2, varscan2
- CHURC1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1430057095, COSV63036262; called by muse, mutect2, varscan2
- CLDN12 | c.584G>C p.W195S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55307039; called by muse, mutect2, varscan2
- CLIC2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58936412, COSV58936822; called by muse, mutect2
- CNTLN | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201402782, COSV52080480, COSV99265829; called by muse, mutect2, varscan2
- COA7 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65299551; called by muse, mutect2
- CSMD1 | c.9657C>A p.D3219E (on ENST00000520002; = p.D3218E on NM_033225.6) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs771912478, COSV59330512; called by muse, mutect2, varscan2
- CSPG4 | c.6495C>G p.Y2165* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100413448; called by muse, mutect2
- DHX15 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as COSV61027142; called by muse, mutect2, varscan2
- DLD | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52738170; called by muse, mutect2, varscan2
- DLK2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99766740; called by muse, mutect2
- DMAC1 | c.171del p.L58* | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV64065817; called by mutect2*, pindel, varscan2*
- ENPP1 | c.2471A>C p.E824A | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV62932688; called by muse, mutect2, varscan2
- FBXO24 | c.491C>T p.S164F (on ENST00000241071 / NM_033506.3; = p.S202F on NM_012172.5) | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as COSV53826414; called by muse, mutect2, varscan2
- GAL3ST1 | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58892707; called by muse, mutect2, varscan2
- GCN1 | c.3985C>G p.H1329D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56108507; called by mutect2, varscan2
- GFPT2 | c.1442G>A p.S481N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53808995; called by muse, mutect2, varscan2
- GLI2 | c.2033C>T p.T678M (on ENST00000361492 / NM_001374353.1; = p.T695M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150858529, COSV58042900; called by muse, mutect2, varscan2
- H2AC20 | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV58612101; called by muse, mutect2, varscan2
- HAS1 | c.1178G>C p.W393S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV55787737; called by muse, mutect2, varscan2
- IGKV3D-7 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217086257; called by muse, mutect2, varscan2
- KAT6B | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.112); catalogued as rs145911926; called by muse, mutect2, varscan2
- LMTK3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1416155276, COSV54312960; called by muse, mutect2, varscan2
- LPCAT4 | c.1573T>C p.*525Rext*14 | Nonstop Mutation (SNP) | VAF 31/304 reads (10%) | catalogued as COSV100148841; called by muse, mutect2, varscan2
- LRP6 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV54385521; called by muse, mutect2, varscan2
- LRRC37A3 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 37/889 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100140859, COSV100141328; called by muse, mutect2
- MDN1 | c.12376G>A p.A4126T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV65522480; called by muse, mutect2, varscan2
- MLYCD | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV52305405; called by muse, mutect2, varscan2
- MUC16 | c.31158C>G p.S10386R | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV101200290, COSV67469364; called by muse, mutect2, varscan2
- MYCBPAP | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV60407838, COSV60408384; called by muse, mutect2, varscan2
- NCAM1 | c.1711G>A p.V571I (on ENST00000316851 / NM_181351.5; = p.V561I on NM_000615.7) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs370003415, COSV57520141; called by muse, mutect2, varscan2
- NOTCH2 | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV56692668; called by muse, mutect2, varscan2
- NTMT1 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99475600; called by muse, mutect2
- OR5AC2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100684304; called by muse, mutect2
- OR6T1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs765590865, COSV100190091, COSV58307265; called by muse, mutect2, varscan2
- PAPOLG | c.2003A>T p.E668V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV53183056; called by muse, mutect2, varscan2
- PITX2 | c.589T>G p.F197V (on ENST00000354925 / NM_001204397.1; = p.F204V on NM_000325.6) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs780968713, COSV60741070; called by muse, mutect2, varscan2
- PMS2 | c.566A>C p.H189P | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs876660330, COSV56221907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PREPL | c.2048A>T p.D683V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53216947; called by muse, mutect2, varscan2
- PVRIG | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV52781329; called by muse, mutect2, varscan2
- REST | c.3189C>G p.I1063M | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100470685; called by muse, mutect2
- RTN4 | c.3296T>G p.V1099G (on ENST00000337526 / NM_020532.5; = p.V106G on NM_007008.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58268316; called by muse, mutect2, varscan2
- SEMA3D | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 18/194 reads (9%) | catalogued as COSV99405885; called by muse, mutect2
- SEPTIN10 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV61780395; called by muse, mutect2, varscan2
- SETD2 | c.1736A>G p.N579S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV57438885; called by muse, mutect2, varscan2
- SHC4 | c.1110_1112del p.E370del | In Frame Del (DEL) | VAF 21/191 reads (11%) | catalogued as rs777762864; called by pindel, varscan2
- SLC4A4 | c.1256_1257insA p.P420Afs*3 (on ENST00000264485 / NM_001098484.3; = p.P376Afs*3 on NM_003759.4) | Frame Shift Ins (INS) | VAF 36/186 reads (19%) | catalogued as COSV52625463; called by mutect2, pindel*, varscan2
- SPRR2E | c.25A>C p.K9Q | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.866); catalogued as COSV100907415; called by muse, varscan2
- SRCAP | c.1349A>T p.Q450L | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1319893455, COSV52673417; called by muse, mutect2, varscan2
- SUPT6H | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 105/409 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58927779; called by muse, mutect2, varscan2
- TARS1 | c.1331A>C p.E444A | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54309464; called by muse, mutect2, varscan2
- TECTA | c.6296C>A p.T2099K | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV50715051; called by muse, mutect2
- TRIM72 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.904); catalogued as COSV57251219; called by muse, mutect2, varscan2
- TTN | c.48598A>G p.N16200D (on ENST00000591111; = p.N8776D on NM_003319.4) | Missense Mutation (SNP) | VAF 83/328 reads (25%) | PolyPhen probably damaging (0.994); catalogued as COSV60097835; called by muse, mutect2, varscan2
- TTN | c.11335del p.H3779Ifs*8 (on ENST00000591111; = p.H3733Ifs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 28/179 reads (16%) | catalogued as COSV60097886; called by mutect2, pindel, varscan2
- URGCP | c.1350C>A p.D450E (on ENST00000453200 / NM_001077663.3; = p.D441E on NM_017920.4) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV56248121; called by mutect2, varscan2
- USP37 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV51443754; called by muse, mutect2, varscan2
- UTP20 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV99880842; called by muse, mutect2
- VPS13A | c.9377G>A p.R3126K | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs777520036, COSV64330227; called by muse, mutect2, varscan2
- VPS37A | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV61365007; called by muse, mutect2, varscan2
- ZNF438 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1232452610, COSV59195624; called by muse, mutect2, varscan2
- ZNF485 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV62424449; called by muse, mutect2, varscan2
- ARMCX2 | c.1630_1640del p.K544Yfs*8 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- DMAC1 | c.172del p.L58* | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- DST | c.5707_5722del p.E1903Lfs*9 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- DST | c.5276del p.L1759* | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- FOXP4 | c.290_300+38del p.X97_splice | Splice Site (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel
- JTB | c.272del p.N91Mfs*10 | Frame Shift Del (DEL) | VAF 46/203 reads (23%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.516dup p.D173* | Frame Shift Ins (INS) | VAF 52/195 reads (27%) | called by mutect2, pindel, varscan2
- PCDH19 | c.2086_2092del p.M696Sfs*22 (on ENST00000373034 / NM_001184880.2; = p.M696Sfs*55 on NM_020766.3) | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13341C>T p.D4447= | Silent (SNP) | VAF 168/444 reads (38%) | catalogued as COSV68947304; called by muse, mutect2, varscan2
- ADGRG4 | c.2862C>T p.P954= | Silent (SNP) | VAF 65/318 reads (20%) | catalogued as COSV54957334; called by muse, mutect2, varscan2
- AOX1 | c.3214C>T p.L1072= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as rs769757908, COSV53496108; called by muse, mutect2, varscan2
- ARHGEF5 | c.4113G>A p.L1371= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as rs759071343, COSV99282576; called by muse, mutect2, varscan2
- ATRX | c.3669A>G p.E1223= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV64877377; called by muse, mutect2, varscan2
- C1orf116 | c.1782G>A p.K594= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV63944145; called by muse, mutect2, varscan2
- CALD1 | c.1245G>A p.G415= | Silent (SNP) | VAF 225/1024 reads (22%) | catalogued as COSV62648351; called by muse, mutect2, varscan2
- CDH26 | c.1119G>T p.P373= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as rs763693105, COSV54847526, COSV54855695; called by muse, mutect2, varscan2
- COMP | c.15C>G p.T5= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV55874985; called by muse, mutect2, varscan2
- CYP3A7 | c.1092C>G p.L364= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as COSV60481703; called by muse, mutect2, varscan2
- DDX53 | c.480C>T p.V160= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs749049454, COSV100028687; called by muse, mutect2
- EYA1 | c.624T>C p.F208= | Silent (SNP) | VAF 34/167 reads (20%) | catalogued as COSV58164117; called by muse, mutect2, varscan2
- FLNA | c.1770C>A p.V590= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs782619869, COSV61043946; called by muse, mutect2, varscan2
- HSD17B10 | c.33G>A p.L11= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1556894950; called by muse, mutect2
- KLHL25 | c.1113G>A p.A371= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs567307438, COSV61995222; called by mutect2, varscan2
- MCTP2 | c.1386T>A p.L462= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV59144690; called by muse, mutect2, varscan2
- MED24 | c.124C>T p.L42= | Silent (SNP) | VAF 11/237 reads (5%) | catalogued as COSV100672985; called by muse, mutect2
- NAE1 | c.819C>T p.N273= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs1188966266, COSV51978056, COSV99322952; called by muse, mutect2
- NKX3-2 | c.808C>T p.L270= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV66711681; called by muse, mutect2, varscan2
- TRIML1 | c.1116T>A p.P372= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV60194519; called by muse, mutect2, varscan2
- CLCN5 | c.17-39155C>G | Intron (SNP) | VAF 53/261 reads (20%) | catalogued as COSV65801427; called by muse, mutect2, varscan2
- PRR12 | c.51+608C>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101330575; called by muse, mutect2
